Somatic mutation profile of tumor specimen TCGA-BA-A4IH-01A (aliquot TCGA-BA-A4IH-01A-11D-A25Y-08) from TCGA case TCGA-BA-A4IH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G3; Age at diagnosis: 57.8 years (21,094 days).
Specimen TCGA-BA-A4IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc3e626d-9ff7-478c-9132-cc41909924cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A4IH-10A (Blood Derived Normal), aliquot TCGA-BA-A4IH-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7f2ba5a-54a6-4ded-9acd-336545d41944

The open-access MAF lists 47 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 36, Silent 7, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as COSV101275968; called by muse, mutect2, varscan2
- APOB | c.3844G>A p.D1282N | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs781366272, COSV99265816; called by muse, mutect2, varscan2
- B3GAT1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.65); PolyPhen benign (0.09); catalogued as rs766472299, COSV56995177, COSV56999691; called by muse, mutect2, varscan2
- C19orf57 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.159); catalogued as rs779190129, COSV100694707; called by muse, mutect2, varscan2
- C6orf58 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV100314904; called by muse, mutect2, varscan2
- CDH24 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs774495471, COSV52982204; called by muse, mutect2, varscan2
- CPNE5 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55195734, COSV99782805; called by muse, mutect2, varscan2
- DAG1 | c.1087C>G p.P363A | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs758190062, COSV100444959; called by muse, mutect2, varscan2
- FAM184A | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV58853146; called by muse, mutect2, varscan2
- FGD2 | c.462C>G p.I154M | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99236203; called by muse, mutect2, varscan2
- GPRC5D | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs751439160, COSV99964241; called by muse, mutect2, varscan2
- GSX2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58842477; called by muse, mutect2, varscan2
- GUCY2C | c.3164A>T p.K1055I | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.149); catalogued as COSV99663694; called by muse, mutect2
- KCNA5 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.039); catalogued as rs771488872, COSV52904153; called by muse, mutect2, varscan2
- LUM | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs756589791, COSV57127642, COSV57128855; called by muse, mutect2, varscan2
- MYH9 | c.2135T>A p.V712E | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99338936; called by muse, mutect2, varscan2
- MYO1D | c.1400C>G p.T467S | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV100554340, COSV59016869; called by muse, mutect2, varscan2
- NIBAN3 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV99962279; called by muse, mutect2, varscan2
- OR2M3 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 137/340 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs1409931924, COSV101513437; called by muse, mutect2, varscan2
- OR5D13 | c.636C>A p.S212R | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100686876; called by muse, mutect2, varscan2
- OR8J3 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100040742, COSV100040856; called by muse, mutect2, varscan2
- PCDHB7 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.02); catalogued as COSV50754871, COSV99177005; called by muse, mutect2, varscan2
- PSD | c.2452A>T p.S818C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99192732; called by muse, mutect2, varscan2
- PTH2R | c.1208C>A p.S403Y | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446582082, COSV99782505; called by muse, mutect2, varscan2
- RXYLT1 | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV54168311, COSV99706918; called by muse, mutect2, varscan2
- SELP | c.1315C>G p.P439A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.792); catalogued as COSV99740073; called by muse, mutect2, varscan2
- SMC2 | c.2484G>T p.E828D | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV99659064; called by muse, mutect2, varscan2
- SYNPO2 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100205661; called by muse, varscan2
- TRIM51 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as rs149512476, COSV99792647; called by muse, mutect2, varscan2
- TRMU | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 23/141 reads (16%) | catalogued as COSV99324563; called by muse, mutect2, varscan2
- UNC79 | c.1624G>A p.D542N (on ENST00000393151 / NM_001346218.2; = p.D365N on NM_020818.5) | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99828029; called by muse, mutect2, varscan2
- USP29 | c.2278G>T p.A760S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.35); catalogued as COSV99518145; called by muse, mutect2, varscan2
- WDFY3 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs775542349, COSV99883715; called by muse, mutect2, varscan2
- XPO7 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 84/198 reads (42%) | catalogued as COSV99381329; called by muse, mutect2, varscan2
- YARS1 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100993419; called by muse, mutect2, varscan2
- ZMYM6 | c.3596G>A p.S1199N | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs186480444, COSV64121192; called by muse, mutect2, varscan2
- ASXL3 | c.3015_3028del p.E1005Dfs*25 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- EPS15L1 | c.1081_1088del p.P361Efs*24 | Frame Shift Del (DEL) | VAF 51/64 reads (80%) | called by mutect2, pindel, varscan2
- SEMA7A | c.1958T>C p.L653P | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FKTN | c.1299G>A p.T433= | Silent (SNP) | VAF 74/155 reads (48%) | catalogued as rs912930168, COSV99795424; called by muse, mutect2, varscan2
- GPR37L1 | c.316C>T p.L106= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV100938555; called by muse, mutect2, varscan2
- LDLRAD2 | c.219C>T p.P73= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs752895868, COSV100760802, COSV60827777; called by muse, mutect2, varscan2
- LRRK1 | c.4569G>T p.P1523= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99439037, COSV99440357; called by muse, mutect2, varscan2
- PCDHGB1 | c.2229T>A p.T743= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV99539040; called by muse, mutect2, varscan2
- RANBP2 | c.861A>T p.G287= | Silent (SNP) | VAF 163/399 reads (41%) | catalogued as COSV99312230; called by muse, mutect2, varscan2
- SRP14 | c.171G>T p.L57= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV99139544; called by muse, mutect2, varscan2
